Surgical pathology report (de-identified scan), TCGA case TCGA-05-4245, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Indivumed, specimen TCGA-05-4245-01A (Primary Tumor).

Diagnosis:

1. Atypical resection material from the indicated upper lobe of the lung with an infiltrate of poorly differentiated and non-mucigenous, pulmonary adenocarcinoma, of max. 3.2 cm in size.

Tumor classification:

M-8140/3, G 3, pT 2, pV 1, pN 2, pM x, stage III A. R0.

Immunohistological follow-up report

In the region of the tumor cells there is an absence of cytokeratin 5 expression. Some of the tumor cells co-express cytokeratin 7 and 20 and most show nuclear expression of TTF-1.

There is also marked CEA expression. The proliferation marker Mib-1 (61-67) moderately high with staining of about 30% of tumor cell nuclei.

Assessment:

The marker spectrum especially with the diffuse and marked nuclear expression of TTF-1 supports the diagnosis of primary pulmonary adenocarcinoma.

Source: NCI Genomic Data Commons file 89b3dd6e-b970-4a18-a3f0-615f7cf89e8c (TCGA-05-4245.902FE548-5B93-49C9-81DB-2AF4A4A88F3C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).